Somatic mutation profile of tumor specimen 0DLZOG from CCDI case PBBZHB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pineoblastoma; Tissue or organ of origin: Pineal gland; Age at diagnosis: 3.7 years (1,349 days).
Specimen 0DLZOG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30e8bb80-6724-4f3d-af84-897a5fcc3064.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLZN9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e1bb858-fd65-4afc-9df1-6da7d39ff96b

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL645922.1 | c.3142C>T p.R1048W | Missense Mutation (SNP) | VAF 84/177 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs745920524; called by muse, varscan2
- OR4K13 | c.739G>T p.V247L | Missense Mutation (SNP) | VAF 39/373 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV100237793; called by muse, varscan2
- ARHGEF40 | c.3338C>G p.P1113R | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, varscan2
- DCHS2 | n.6127-8T>A | Splice Region (SNP) | VAF 82/414 reads (20%) | called by muse, varscan2
- SERBP1 | c.929A>T p.K310I (on ENST00000370995 / NM_001018067.2; = p.K289I on NM_015640.4) | Missense Mutation (SNP) | VAF 88/574 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
